Gene-level copy-number profile of tumor specimen MP2PRT-PASKPJ-TMP1-A from MP2PRT case MP2PRT-PASKPJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,594 days).
Specimen MP2PRT-PASKPJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 72194c2b-269e-4ac9-ad2a-8f5cc43af4a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASKPJ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/d16d6142-fd6f-4855-a314-59b649dbaa01

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 747; copy number 1: 4,246; copy number 2: 53,907; copy number 3: 2.

Homozygous deletions (total copy number 0; autosomes only): 747 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,519,354–28,193,936, 79 genes (broad region; genes not listed).
- chr2:88,811,186–89,234,912, 40 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr6:32,439,878–32,589,848, 6 genes: HLA-DRA, HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr6:37,091,314–37,175,428, 2 genes: RPL12P2, PIM1.
- chr7:38,256,337–38,311,808, 9 genes (within-gene range 0–2): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes (within-gene range 0–2): AL449423.1, CDKN2B.
- chr9:112,486,827–112,669,397, 2 genes (within-gene range 0–2): KIAA1958, AL445187.1.
- chr12:6,852,148–13,142,521, 287 genes (broad region; genes not listed).
- chr12:14,250,232–15,006,999, 24 genes: RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489.
- chr14:21,918,188–22,552,156, 112 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,704,286, 168 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,219,647–22,245,515, 4 genes: IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.
- chr22:28,687,743–28,800,597, 4 genes: CHEK2, HSCB, CCDC117, XBP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,390. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
